Somatic mutation profile of tumor specimen MP2PRT-PANVIB-TMP1-A (aliquot MP2PRT-PANVIB-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANVIB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,040 days).
Specimen MP2PRT-PANVIB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc4846e2-1166-4378-9d65-a0ad659338dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANVIB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANVIB-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d984507a-0028-4cab-a806-eaaedb85f510

The open-access MAF lists 16 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 13, Frame Shift Ins 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 60/311 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 44/360 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ARHGAP9 | c.1493G>A p.R498Q (on ENST00000393797 / NM_001319850.2; = p.R479Q on NM_032496.4) | Missense Mutation (SNP) | VAF 170/376 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.665); catalogued as rs746906711; called by muse, varscan2
- GSDMD | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 98/239 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.133); catalogued as rs1405530233; called by muse, mutect2, varscan2
- LAMA2 | c.4763G>A p.R1588H | Missense Mutation (SNP) | VAF 53/400 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as rs138765295, COSV70349027; called by muse, mutect2, varscan2
- MYC | c.1105G>A p.E369K (on ENST00000377970; = p.E384K on NM_002467.6) | Missense Mutation (SNP) | VAF 28/464 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV52372750; called by muse, mutect2
- OVOL3 | c.550C>T p.R184C (on ENST00000585332; = p.R160C on NM_001302757.1) | Missense Mutation (SNP) | VAF 208/539 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs1452194241; called by muse, mutect2, varscan2
- RBM24 | c.607G>A p.A203T (on ENST00000379052 / NM_001143942.2; = p.A158T on NM_153020.2) | Missense Mutation (SNP) | VAF 29/595 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs772282132; called by muse, mutect2
- SETD2 | c.5056C>T p.R1686W | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100340335; called by muse, mutect2
- GPR158 | c.2252G>A p.G751D | Missense Mutation (SNP) | VAF 32/764 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GUCY2F | c.1099A>C p.M367L | Missense Mutation (SNP) | VAF 13/337 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- IGHV4-59 | c.345_346insCCACG p.R116Pfs*? | Frame Shift Ins (INS) | VAF 58/435 reads (13%) | called by pindel, varscan2
- OR13C3 | c.485A>G p.Y162C | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRDV2 | chr14:22423041 ins CGTT | Frame Shift Ins (INS) | VAF 32/137 reads (23%) | called by mutect2, pindel, varscan2
- VEGFC | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2
- DLGAP2 | c.516G>A p.T172= | Silent (SNP) | VAF 66/988 reads (7%) | catalogued as rs368834607; called by muse, mutect2
